Somatic mutation profile of tumor specimen TARGET-15-SJMPAL016342-09A.3 (aliquot TARGET-15-SJMPAL016342-09A.3-01D) from TARGET case TARGET-15-SJMPAL016342, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 0.9 years (335 days).
Specimen TARGET-15-SJMPAL016342-09A.3: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e91bab6-b778-40b1-9786-ac50f7c0e4c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL016342-14A.1 (Bone Marrow Normal), aliquot TARGET-15-SJMPAL016342-14A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/34ea537e-b24a-488e-99b3-d64fe5e4cf77

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH8 | c.11307C>A p.D3769E | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.38); called by muse, mutect2
- ILF2 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 9/215 reads (4%) | SIFT tolerated (0.75); PolyPhen benign (0.074); called by muse, mutect2
- MAP1B | c.3444C>A p.N1148K | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.702); called by muse, mutect2
- RBSN | c.1102G>T p.E368* | Nonsense Mutation (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- AC024651.2 | chr15:97873957 C>A | 5'Flank (SNP) | VAF 3/19 reads (16%) | catalogued as rs1037337776; called by muse, mutect2
